Gene-level copy-number profile of tumor specimen TCGA-CC-A7IF-01A from TCGA case TCGA-CC-A7IF, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G1; Age at diagnosis: 59.8 years (21,845 days).
Specimen TCGA-CC-A7IF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.bb4c1513-229b-4c9e-a01e-4d9ac19deff0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CC-A7IF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/275b1cde-6ffb-44e0-8ec5-88c5ec4ebb04

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 737; copy number 2: 6,120; copy number 3: 9,255; copy number 4: 35,638; copy number 5: 3,266; copy number 6: 2,080; copy number 7: 1,189; copy number 8: 289; copy number 9: 354; copy number 10: 857; copy number 11: 19; copy number 12: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CC-A7IF-01A-11D-A33B-01): tumor purity 0.76, ploidy 3.97, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,232 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:91,909,738–99,013,743, 139 genes, copy number 10 (broad region; genes not listed).
- chr8:99,091,738–99,094,060, 1 gene, copy number 10: AC107909.2.
- chr8:99,613,783–145,066,685, 716 genes, copy number 10 (broad region; genes not listed).
- chr16:46,469,341–47,035,385, 22 genes, copy number 10–12 (within-gene range 2–12): ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6, MYLK3, AC007225.1, C16orf87, CKBP1, AC007225.2, GPT2, DNAJA2, AC018845.3, AC018845.1, AC018845.2.
- chr17:58,420,167–71,013,587, 354 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 737. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
